Gene-level copy-number profile of tumor specimen MP2PRT-PASYKN-TTP1-A from MP2PRT case MP2PRT-PASYKN, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.5 years (1,276 days).
Specimen MP2PRT-PASYKN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 574a06fd-9982-4edc-bf61-17986bfc480b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASYKN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/972d2f2d-7afe-44b3-bc18-3d5323645b31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 4,114; copy number 2: 51,565; copy number 3: 85; copy number 6: 2,524.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:27,506,830–34,102,610, 106 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:9,975,017–10,137,004, 4 genes (within-gene range 0–2): CR382285.1, CR382285.2, CR382287.1, CDRT15P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,524 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,092. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
